Somatic mutation profile of tumor specimen TCGA-EE-A2GP-06A (aliquot TCGA-EE-A2GP-06A-11D-A197-08) from TCGA case TCGA-EE-A2GP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 81.5 years (29,759 days).
Specimen TCGA-EE-A2GP-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e7647b1-ab90-4153-9e26-afd2cec68c54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GP-10A (Blood Derived Normal), aliquot TCGA-EE-A2GP-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ae18f0d-4440-4a21-a786-ecc940ba4f34

The open-access MAF lists 764 somatic variants for this specimen: 489 protein-altering or splice-affecting, 256 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 447, Silent 256, Nonsense Mutation 27, RNA 8, Intron 6, Splice Region 6, Splice Site 5, 5'Flank 3, Frame Shift Ins 2, 3'UTR 2, Frame Shift Del 1, Translation Start Site 1.

Variants (750 of 764; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 49/80 reads (61%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 164/278 reads (59%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PBX1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1553249136, COSV63344026; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 36/57 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs866434111, COSV50957596; called by muse, mutect2, varscan2
- ABCA12 | c.4831G>A p.D1611N (on ENST00000272895 / NM_173076.3; = p.D1293N on NM_015657.3) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.405); catalogued as rs775054797, COSV55959959; called by muse, mutect2, varscan2
- ABCB11 | c.3691C>T p.R1231W | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766285158, CM067623, COSV55591407; called by muse, varscan2
- ABCC6 | c.4283C>A p.A1428D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763908026, COSV52744128; called by muse, mutect2, varscan2
- ABCF3 | c.918G>A p.R306= | Splice Region (SNP) | VAF 33/95 reads (35%) | catalogued as rs1560134049, COSV53048150; called by muse, mutect2, varscan2
- AC136428.1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 135/322 reads (42%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs780492113; called by muse, mutect2, varscan2
- ADAM33 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62934848; called by muse, mutect2, varscan2
- ADAMTS16 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV56990571; called by muse, mutect2, varscan2
- ADAMTS6 | c.2186G>A p.R729K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0.05); catalogued as COSV66859897; called by muse, mutect2, varscan2
- ADAMTS7 | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs746384227, COSV101183109, COSV101183282; called by muse, mutect2, varscan2
- ADGRE3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.03); catalogued as rs1166647173, COSV53730748; called by muse, mutect2, varscan2
- ADGRG4 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54956514; called by muse, mutect2, varscan2
- ADH7 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as rs759568380, COSV52920929; called by muse, mutect2, varscan2
- ADTRP | c.44G>A p.S15N | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV57643212; called by muse, mutect2, varscan2
- AFAP1L2 | c.2387C>T p.S796L (on ENST00000304129 / NM_001351075.1; = p.S792L on NM_032550.3 and 11 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs750404595, COSV58415064; called by muse, mutect2, varscan2
- AFF2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 78/98 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV53983599, COSV53990300; called by muse, mutect2, varscan2
- AHNAK2 | c.8167G>A p.E2723K | Missense Mutation (SNP) | VAF 115/171 reads (67%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.858); catalogued as rs183733494, COSV60915865; called by muse, mutect2, varscan2
- AHRR | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.601); catalogued as COSV57086522; called by muse, mutect2, varscan2
- AKR1D1 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs760551876, COSV54337632; called by muse, mutect2, varscan2
- AMBRA1 | c.1436C>T p.T479I (on ENST00000458649 / NM_001367468.1; = p.T389I on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as rs1302694111, COSV54054297; called by muse, mutect2, varscan2
- AMER3 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV58466890; called by muse, mutect2, varscan2
- ANAPC2 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as rs764001056, COSV59244550; called by muse, mutect2, varscan2
- ANKRD45 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV60961136; called by muse, mutect2, varscan2
- ANO2 | c.2920C>T p.R974W (on ENST00000356134 / NM_001278597.3; = p.R978W on NM_001278596.3) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs751453525, COSV59009548; called by muse, mutect2, varscan2
- ANO3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs754306957, COSV56785250, COSV56806565; called by muse, mutect2, varscan2
- AP2B1 | c.1059G>T p.Q353H | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV51999664; called by muse, mutect2, varscan2
- ARHGAP10 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV60599674; called by muse, mutect2, varscan2
- ARHGDIB | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755743098, COSV56763010; called by muse, mutect2, varscan2
- ARHGEF2 | c.2798C>T p.P933L (on ENST00000361247 / NM_001162383.2; = p.P905L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58117184; called by muse, varscan2
- ARID5B | c.3524C>T p.P1175L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54420854; called by muse, mutect2, varscan2
- ARMC9 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.848); catalogued as COSV63021006; called by muse, mutect2, varscan2
- ASL | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59188462; called by muse, mutect2, varscan2
- ATG2A | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV101034404; called by muse, mutect2, varscan2
- ATG5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1158686992, COSV58347908; called by muse, mutect2, varscan2
- ATP10D | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs150738679; called by muse, mutect2, varscan2
- ATP10D | c.4169C>T p.S1390F | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs112565536, COSV56689990; called by muse, mutect2, varscan2
- ATP2A1 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369818510; called by muse, mutect2, varscan2
- ATP7B | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as COSV54438700; called by muse, mutect2, varscan2
- ATXN7L2 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 22/849 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV60204914; called by muse, mutect2
- BAALC | c.515G>A p.R172Q (on ENST00000297574 / NM_001364874.1; = p.R137Q on NM_024812.3) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs781324772, COSV52562385; called by muse, mutect2, varscan2
- BANF2 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV55724764; called by muse, mutect2, varscan2
- BAZ1B | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV59991342; called by muse, mutect2, varscan2
- BMX | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 97/131 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59591474; called by muse, mutect2, varscan2
- BNC1 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs867490182, COSV61757522; called by muse, mutect2, varscan2
- BNC2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66147796; called by muse, mutect2, varscan2
- BOD1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV53632583; called by muse, mutect2, varscan2
- BRD8 | c.1787C>T p.P596L (on ENST00000254900 / NM_139199.2; = p.P669L on NM_006696.4) | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV50149430; called by muse, mutect2, varscan2
- C10orf82 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65024649; called by muse, mutect2, varscan2
- C12orf50 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV53895343; called by muse, mutect2, varscan2
- C1orf127 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 35/81 reads (43%) | catalogued as rs770718327, COSV65437343; called by muse, mutect2, varscan2
- CACNA1E | c.6356C>T p.S2119F (on ENST00000367573 / NM_001205293.3; = p.S2076F on NM_000721.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV62382429; called by muse, mutect2
- CACNA1H | c.6298G>A p.E2100K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52354659; called by muse, mutect2, varscan2
- CACNA2D2 | c.2644G>A p.E882K (on ENST00000479441 / NM_001174051.3; = p.E875K on NM_006030.4) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.364); catalogued as rs140562117; called by muse, mutect2, varscan2
- CACNG3 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482242077, COSV99136244, COSV99137342; called by mutect2, varscan2
- CACNG3 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50083751, COSV99135606; called by muse, mutect2, varscan2
- CALHM6 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 45/79 reads (57%) | catalogued as COSV63991584; called by muse, mutect2, varscan2
- CAMKV | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV56554331; called by muse, mutect2, varscan2
- CAMP | c.484G>A p.D162N (on ENST00000296435; = p.D159N on NM_004345.5) | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.616); catalogued as COSV56481747; called by muse, mutect2, varscan2
- CAND2 | c.2447C>T p.P816L (on ENST00000456430 / NM_001162499.2; = p.P723L on NM_012298.3) | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV55990201; called by muse, mutect2, varscan2
- CASP7 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61881841; called by muse, mutect2, varscan2
- CATSPER2 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.783); catalogued as COSV58660880; called by muse, mutect2, varscan2
- CBLIF | c.756G>A p.M252I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57239009; called by muse, mutect2, varscan2
- CBX7 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV53359115; called by muse, mutect2, varscan2
- CBY2 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs776992104, COSV60118367; called by muse, mutect2
- CCDC18 | c.2053C>T p.H685Y (on ENST00000343253 / NM_001306076.1; = p.H686Y on NM_206886.4) | Missense Mutation (SNP) | VAF 99/371 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV58143719; called by muse, mutect2, varscan2
- CCDC38 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.214); catalogued as rs1454176262, COSV57136641; called by muse, mutect2, varscan2
- CCDC97 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs201767377, COSV54190374, COSV54191488; called by muse, mutect2, varscan2
- CCNT2 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV51473235; called by muse, mutect2, varscan2
- CCR2 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 147/451 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.317); catalogued as rs746514238, COSV52747978, COSV99432909; called by muse, mutect2, varscan2
- CD1E | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs867813346, COSV63770393; called by muse, mutect2, varscan2
- CD2 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 90/214 reads (42%) | catalogued as rs267597947, COSV65644272; called by muse, mutect2, varscan2
- CD6 | c.920G>A p.G307D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57838752; called by muse, mutect2, varscan2
- CD84 | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 50/121 reads (41%) | catalogued as COSV60867014; called by muse, mutect2, varscan2
- CDC42BPG | c.3313C>T p.R1105* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | catalogued as rs772213290, COSV61345287; called by muse, mutect2, varscan2
- CDCP1 | c.2096A>G p.N699S | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV56105547; called by muse, mutect2, varscan2
- CDH18 | c.1512+1G>A p.X504_splice | Splice Site (SNP) | VAF 14/29 reads (48%) | catalogued as COSV56923654; called by muse, mutect2, varscan2
- CDH23 | c.7325G>A p.G2442E | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.929); catalogued as COSV56464963; called by muse, mutect2, varscan2
- CDK18 | c.841C>T p.R281W (on ENST00000506784 / NM_212503.3; = p.R251W on NM_002596.4) | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141496311, COSV63729171; called by muse, mutect2, varscan2
- CEP250 | c.5927C>T p.A1976V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV100698939; called by muse, mutect2
- CFAP54 | c.5987G>A p.G1996E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs774292976, COSV61571731; called by muse, mutect2, varscan2
- CFAP54 | c.7531C>T p.R2511W | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs552288200, COSV61572335; called by muse, mutect2, varscan2
- CFAP54 | c.7729G>A p.D2577N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV61572341; called by muse, mutect2, varscan2
- CFAP65 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV58561219; called by muse, mutect2, varscan2
- CFAP92 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs757196550, COSV54047483; called by muse, mutect2, varscan2
- CFH | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.535); catalogued as COSV66408729; called by muse, mutect2, varscan2
- CFTR | c.3473G>A p.R1158Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as rs763401376, COSV50054619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD2 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV59120478; called by muse, mutect2
- CHD2 | c.4096C>T p.P1366S | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs1195925017, COSV67709625; called by muse, mutect2, varscan2
- CHD5 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs142551574, COSV52415111; called by muse, mutect2, varscan2
- CHIT1 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV55146997; called by muse, mutect2, varscan2
- CHRM3 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1406659374, COSV55086402; called by muse, mutect2
- CHRNA6 | c.160A>T p.N54Y | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52379583; called by muse, mutect2, varscan2
- CLEC17A | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV60427863; called by muse, mutect2, varscan2
- CLN8 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.337); catalogued as rs541994118, COSV58670535; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CMYA5 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV71406056; called by muse, mutect2, varscan2
- CNGA1 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.364); catalogued as COSV62054341; called by muse, mutect2, varscan2
- CNGB3 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1445668366, COSV60690209; called by muse, mutect2, varscan2
- CNTN5 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as rs267603260, COSV54278153; called by muse, mutect2, varscan2
- CNTN5 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.486); catalogued as rs1489941088, COSV54278175; called by muse, mutect2, varscan2
- COL11A1 | c.3007G>A p.G1003R | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62184135; called by muse, mutect2, varscan2
- COL3A1 | c.2801C>T p.S934L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs753621331, COSV58588341; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL3A1 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58588352; called by muse, mutect2, varscan2
- COL9A1 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.328); catalogued as rs1408064118, COSV57884180; called by muse, mutect2, varscan2
- COL9A1 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 28/39 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as rs1305288562, COSV57884209; called by muse, mutect2, varscan2
- CPNE9 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs941025764, COSV56068531; called by muse, mutect2, varscan2
- CR2 | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.542); catalogued as COSV65507704; called by muse, mutect2
- CRB1 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.348); catalogued as COSV66341329; called by muse, mutect2, varscan2
- CREBBP | c.3884T>C p.V1295A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV52124482; called by muse, mutect2
- CRIP3 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1225841971, COSV51484068; called by muse, mutect2, varscan2
- CSMD1 | c.4459G>A p.D1487N (on ENST00000520002; = p.D1486N on NM_033225.6) | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59326915; called by muse, mutect2, varscan2
- CSMD1 | c.1591C>T p.P531S (on ENST00000520002; = p.P530S on NM_033225.6) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59326943; called by muse, mutect2
- CTIF | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs772233727, COSV56483985; called by muse, mutect2, varscan2
- CTNND2 | c.1696G>A p.V566I | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV100481717, COSV58890471; called by muse, mutect2, varscan2
- CYHR1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs372867926; called by muse, mutect2, varscan2
- CYP4F12 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs533856938, COSV61173866; called by muse, mutect2
- CYP4F2 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | catalogued as COSV50001330; called by muse, mutect2, varscan2
- CYP4F3 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV55410079; called by muse, mutect2, varscan2
- DCAF6 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.359); catalogued as rs769457841, COSV56579033; called by muse, mutect2, varscan2
- DISP3 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1257596807, COSV53827852; called by muse, mutect2, varscan2
- DLEC1 | c.3685G>A p.E1229K | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV57300034; called by muse, mutect2, varscan2
- DLGAP3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs527841852, COSV52393350; called by muse, mutect2, varscan2
- DNAH2 | c.5851-1G>A p.X1951_splice | Splice Site (SNP) | VAF 92/146 reads (63%) | catalogued as COSV66717201, COSV66719863; called by muse, mutect2, varscan2
- DNAH5 | c.4736C>T p.S1579L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs184151103, COSV54226096; called by muse, mutect2, varscan2
- DNAH6 | c.1721G>A p.G574E | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761847218, COSV52862492; called by muse, mutect2, varscan2
- DNAH7 | c.8125G>T p.E2709* | Nonsense Mutation (SNP) | VAF 21/39 reads (54%) | catalogued as COSV56765906, COSV56771810; called by muse, mutect2, varscan2
- DNAH8 | c.10117G>A p.E3373K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV59438136, COSV59443661; called by muse, mutect2, varscan2
- DNAH9 | c.5025+1G>T p.X1675_splice | Splice Site (SNP) | VAF 22/36 reads (61%) | catalogued as COSV52350510; called by muse, mutect2, varscan2
- DNAJC3 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs1178783483, COSV65131022, COSV65131556; called by muse, mutect2, varscan2
- DNPH1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52728779; called by muse, mutect2, varscan2
- DPPA4 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 51/129 reads (40%) | catalogued as COSV59510487; called by muse, mutect2, varscan2
- DPYD | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 107/198 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.043); catalogued as rs867232786, COSV64598066; called by muse, mutect2, varscan2
- DSP | c.5390G>A p.R1797K | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV65792914; called by muse, mutect2, varscan2
- DTL | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs753383449, COSV65342402, COSV65342415; called by muse, mutect2, varscan2
- DUOX2 | c.3251G>A p.R1084Q | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs558919433, CM164602, COSV66532259; called by muse, mutect2, varscan2
- E2F2 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV62276434; called by muse, mutect2, varscan2
- ECEL1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as COSV58812400; called by muse, mutect2, varscan2
- EEF1A2 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); catalogued as COSV53206220; called by muse, mutect2
- EHBP1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.564); catalogued as COSV50416086; called by muse, mutect2, varscan2
- EIF3J | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55995186; called by muse, mutect2, varscan2
- ENOX1 | c.1887A>T p.E629D | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV54899972; called by muse, mutect2, varscan2
- EOMES | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs868242390, COSV55412579; called by muse, mutect2, varscan2
- EP400 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV57772710; called by muse, mutect2, varscan2
- EPHB3 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV57806075; called by muse, mutect2, varscan2
- EPHB6 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV67418616; called by muse, mutect2, varscan2
- EPHX4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV64889528; called by muse, mutect2, varscan2
- ERICH3 | c.3814G>A p.E1272K | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV58607176; called by muse, varscan2
- EVPL | c.5372C>T p.S1791F | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV56911169; called by muse, mutect2, varscan2
- EXTL1 | c.572G>C p.R191P | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65337604; called by muse, mutect2, varscan2
- EXTL3 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV55038131; called by muse, mutect2, varscan2
- EYA4 | c.1249G>A p.E417K (on ENST00000531901 / NM_001301013.1; = p.E411K on NM_004100.5) | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV62047479, COSV62052492; called by muse, mutect2, varscan2
- FAM104A | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV55276707; called by muse, mutect2, varscan2
- FAM120C | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.555); catalogued as COSV60259519; called by muse, mutect2
- FAM135B | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52709409, COSV52726334; called by muse, mutect2, varscan2
- FAM151A | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs763297462, COSV56364252; called by muse, mutect2, varscan2
- FAM200A | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs757343996, COSV68808593; called by muse, mutect2, varscan2
- FAM71B | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 353/674 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs781501763, COSV57228351; called by muse, mutect2, varscan2
- FAT3 | c.1463G>A p.G488E | Missense Mutation (SNP) | VAF 246/638 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs369038969; called by muse, varscan2
- FAT3 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 286/777 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.763); catalogued as rs367795074, COSV53113596; called by muse, varscan2
- FAT3 | c.9904G>A p.E3302K | Missense Mutation (SNP) | VAF 286/759 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53113632; called by muse, mutect2, varscan2
- FCGBP | c.10604-1G>A p.X3535_splice | Splice Site (SNP) | VAF 9/40 reads (23%) | catalogued as rs1332235561; called by muse, mutect2, varscan2
- FCRL5 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1181237308, COSV62514429, COSV99052689; called by muse, mutect2, varscan2
- FCRL5 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62518875; called by muse, mutect2, varscan2
- FER1L6 | c.2533G>A p.G845R | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67550048; called by muse, mutect2, varscan2
- FLG2 | c.6625G>A p.G2209R | Missense Mutation (SNP) | VAF 141/310 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV66168866; called by muse, mutect2, varscan2
- FLNC | c.1082G>C p.R361P | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV57955298, COSV57956205; called by muse, mutect2, varscan2
- FLRT1 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.206); catalogued as COSV55360739; called by muse, mutect2, varscan2
- FMNL2 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56490889; called by muse, mutect2, varscan2
- FREM2 | c.7295G>A p.R2432Q | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs746001237, COSV54836577, COSV99746666; called by muse, mutect2, varscan2
- FSIP2 | c.18958G>A p.E6320K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV58086797; called by muse, mutect2
- GAS2 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200391147, COSV53407696; called by muse, mutect2, varscan2
- GIPC1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100600082; called by muse, mutect2, varscan2
- GLIS1 | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs775863621, COSV56549022; called by muse, mutect2, varscan2
- GLRB | c.1441T>A p.F481I | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52417086; called by muse, mutect2, varscan2
- GOLGB1 | c.6872C>T p.S2291F | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs1022926968, COSV61466065; called by muse, mutect2, varscan2
- GPAT3 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs267600279, COSV52357098; called by muse, mutect2, varscan2
- GPM6A | c.341A>G p.Y114C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54543261; called by muse, mutect2, varscan2
- GPR45 | c.1031A>T p.Q344L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV51524106; called by muse, mutect2, varscan2
- GPR61 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63983796; called by muse, mutect2, varscan2
- GRIA2 | c.2438T>A p.V813D | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52391190; called by muse, mutect2, varscan2
- GRID2 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56181872; called by muse, mutect2, varscan2
- GRIK4 | c.2431G>A p.V811I | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs1186304566, COSV70802423; called by muse, mutect2, varscan2
- GSN | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.332); catalogued as rs749370822, COSV57997597; called by muse, mutect2
- GSN | c.2221C>G p.R741G | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as COSV57997622, COSV57999568; called by muse, mutect2
- HCN4 | c.2564C>A p.S855Y | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV56082227, COSV56083720; called by muse, mutect2, varscan2
- HCRTR2 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV63795995; called by muse, mutect2, varscan2
- HEATR5A | c.6052G>A p.E2018K | Missense Mutation (SNP) | VAF 84/120 reads (70%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.511); catalogued as COSV66341051; called by muse, mutect2, varscan2
- HELZ2 | c.4591C>T p.Q1531* (on ENST00000467148 / NM_001037335.2; = p.Q962* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV71295958; called by muse, mutect2
- HELZ2 | c.3187C>T p.P1063S (on ENST00000467148 / NM_001037335.2; = p.P494S on NM_033405.3) | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs985156719, COSV100915595; called by muse, mutect2, varscan2
- HIPK4 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV52521210; called by muse, mutect2, varscan2
- HIVEP1 | c.4961C>T p.S1654F | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV65101595; called by muse, mutect2, varscan2
- HMCN1 | c.10672C>T p.P3558S | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54901969; called by muse, mutect2, varscan2
- HNF4G | c.412G>A p.D138N (on ENST00000354370 / NM_001330561.2; = p.D185N on NM_004133.5) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769288145, COSV62968769; called by muse, mutect2, varscan2
- HNRNPCL1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.302); catalogued as rs779197063, COSV58611618; called by muse, mutect2, varscan2
- HRNR | c.2779G>A p.G927S | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.452); catalogued as rs755309371, COSV64258166, COSV64261617; called by muse, mutect2, varscan2
- HSD17B12 | c.622T>C p.F208L | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53499723; called by muse, mutect2, varscan2
- HTT | c.8330C>T p.P2777L | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100750798; called by muse, mutect2, varscan2
- IBSP | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as rs1276607757, COSV56895806; called by muse, mutect2, varscan2
- IFIH1 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.025); catalogued as COSV55125306; called by muse, mutect2, varscan2
- INTU | c.884T>C p.V295A | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56539915; called by muse, mutect2, varscan2
- IQCB1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 128/292 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs917267308, COSV60437591, COSV60439884; called by muse, mutect2, varscan2
- IQSEC3 | c.3175G>A p.G1059R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV58285066; called by muse, mutect2, varscan2
- ITGA5 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.866); catalogued as COSV53217826; called by muse, mutect2, varscan2
- ITGB2 | c.1729G>T p.G577W (on ENST00000302347; = p.G553W on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV100185884, COSV56608389; called by muse, mutect2, varscan2
- ITGB2 | c.1728G>A p.P576= (on ENST00000302347; = p.P552= on NM_000211.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 32/74 reads (43%) | catalogued as rs759039359, COSV100185887; called by muse, mutect2, varscan2
- ITGB5 | c.1615G>C p.E539Q | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV56149183; called by muse, mutect2, varscan2
- ITGBL1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1405523166, COSV66005791; called by muse, mutect2, varscan2
- JAM2 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 133/260 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV57257601; called by muse, mutect2, varscan2
- JHY | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as COSV57075378; called by muse, mutect2, varscan2
- KAT2B | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55429571; called by muse, mutect2, varscan2
- KAZN | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63208026; called by muse, mutect2, varscan2
- KCND2 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.627); catalogued as rs749225363, COSV58580826; called by muse, mutect2, varscan2
- KCND3 | c.1799G>A p.G600E | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV56181182; called by muse, mutect2, varscan2
- KCNG1 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as COSV65369139, COSV65370294; called by muse, mutect2, varscan2
- KCNH7 | c.465G>A p.R155= | Splice Region (SNP) | VAF 34/66 reads (52%) | catalogued as COSV59794266; called by muse, mutect2, varscan2
- KCNH8 | c.2654G>A p.G885D | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs772824016, COSV60464277; called by muse, mutect2, varscan2
- KCNJ14 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs1263322863, COSV60738011; called by muse, mutect2, varscan2
- KCNJ6 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV55714515; called by muse, mutect2, varscan2
- KCNK5 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs1050062838, COSV63988927; called by muse, mutect2, varscan2
- KCNMB4 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV50691474; called by muse, mutect2, varscan2
- KCNU1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.945); catalogued as COSV67756180; called by muse, mutect2, varscan2
- KDM2B | c.3454C>T p.R1152W | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs782644211, COSV100997419; called by muse, mutect2, varscan2
- KIAA1549 | c.4045A>G p.S1349G | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54314685; called by muse, mutect2, varscan2
- KIAA1549L | c.1160T>A p.I387K (on ENST00000321505; = p.I684K on NM_012194.3) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV55774126; called by muse, mutect2, varscan2
- KIF21B | c.4094C>T p.S1365F (on ENST00000422435 / NM_001252100.2; = p.S1352F on NM_017596.4) | Missense Mutation (SNP) | VAF 94/203 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV59758236; called by muse, mutect2, varscan2
- KIF2B | c.1672G>A p.G558R | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as COSV52130762, COSV52136291; called by muse, mutect2, varscan2
- KIF5A | c.2538G>A p.Q846= | Splice Region (SNP) | VAF 28/83 reads (34%) | catalogued as COSV54053525, COSV99672469; called by muse, mutect2, varscan2
- KLHL8 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 54/138 reads (39%) | catalogued as rs549853074, COSV56747892; called by muse, mutect2, varscan2
- KRTAP5-5 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV68784284; called by muse, varscan2
- LAMA3 | c.8977C>T p.P2993S (on ENST00000313654 / NM_198129.4; = p.P1384S on NM_000227.6) | Missense Mutation (SNP) | VAF 94/168 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as COSV52533701; called by muse, mutect2, varscan2
- LARP4 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1406435935, COSV53322735; called by muse, mutect2, varscan2
- LCE1B | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV63980321; called by muse, mutect2, varscan2
- LEFTY1 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1230044288, COSV55283017; called by muse, mutect2, varscan2
- LGR4 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV64864426; called by muse, mutect2, varscan2
- LILRA2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as COSV52192017; called by muse, mutect2, varscan2
- LILRB2 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1329343863, COSV58745418; called by muse, mutect2, varscan2
- LIPH | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 155/381 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs376062316, COSV56184073; called by muse, mutect2, varscan2
- LMX1A | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.164); catalogued as rs1282464728, COSV54221439; called by muse, mutect2, varscan2
- LRP1 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.08); catalogued as rs758251459, COSV54511836; called by muse, mutect2
- LRP1 | c.6485C>T p.A2162V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV54511848; called by muse, mutect2, varscan2
- LRP1B | c.7523C>T p.S2508F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1393251553, COSV67193597; called by muse, mutect2
- LRP3 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs576430531, COSV53504139; called by muse, mutect2, varscan2
- LRRC4C | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV53426387; called by muse, mutect2, varscan2
- LSR | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100670460, COSV61555148; called by muse, mutect2, varscan2
- LVRN | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs759229863, COSV100773473; called by muse, mutect2, varscan2
- MACIR | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV60635082; called by muse, mutect2, varscan2
- MAGEA4 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 92/122 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52341412; called by muse, mutect2, varscan2
- MAPK6 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55930021; called by muse, mutect2, varscan2
- MARCO | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV59054567; called by muse, mutect2, varscan2
- MARVELD2 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.797); catalogued as COSV57780151; called by muse, mutect2, varscan2
- MCEMP1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.171); catalogued as rs139191722, COSV58039436; called by muse, mutect2
- MCF2L2 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs1450813503, COSV61053896; called by muse, mutect2, varscan2
- MCUR1 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs747823216, COSV63958015; called by muse, mutect2, varscan2
- MECOM | c.1756G>A p.D586N (on ENST00000468789 / NM_001105078.4; = p.D774N on NM_004991.4) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52963760; called by muse, mutect2, varscan2
- MED13L | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV56120398; called by muse, mutect2, varscan2
- MEGF11 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV56551104; called by muse, mutect2, varscan2
- MICALL1 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as rs778087097, COSV53240847; called by muse, mutect2, varscan2
- MICALL2 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs1179089037, COSV52515927; called by muse, mutect2, varscan2
- MLN | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV56475241; called by muse, mutect2, varscan2
- MLPH | c.190T>C p.C64R | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781041118, COSV52820699; called by muse, mutect2, varscan2
- MMP25 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV60679313, COSV60679630; called by muse, mutect2, varscan2
- MORN3 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.89); PolyPhen benign (0.109); catalogued as COSV62507358; called by muse, mutect2
- MUC16 | c.37435G>A p.E12479K | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as COSV67467600; called by muse, mutect2, varscan2
- MUC16 | c.35687C>T p.S11896F | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as rs1568727347, COSV67448653; called by muse, mutect2, varscan2
- MUC16 | c.2804C>T p.A935V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV67467612; called by muse, mutect2, varscan2
- MUC17 | c.3754A>C p.T1252P | Missense Mutation (SNP) | VAF 158/379 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV60289250; called by muse, mutect2, varscan2
- MX2 | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58096583; called by muse, mutect2, varscan2
- MXRA5 | c.8038G>A p.E2680K | Missense Mutation (SNP) | VAF 49/67 reads (73%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.497); catalogued as COSV99477070; called by muse, mutect2, varscan2
- MYBPC2 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs747255135, COSV63095686; called by muse, mutect2
- MYCBP2 | c.10415T>C p.V3472A (on ENST00000357337; = p.V3510A on NM_015057.5) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.193); catalogued as COSV62020078; called by muse, mutect2
- MYO16 | c.1417C>T p.L473F | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV51795385; called by muse, mutect2, varscan2
- MYO1C | c.2429A>G p.D810G (on ENST00000648651 / NM_001080779.2; = p.D775G on NM_033375.5) | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV62999178; called by muse, mutect2, varscan2
- MYO3A | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs777460208, COSV56321563, COSV56347634; called by muse, mutect2
- MYO3B | c.1918G>A p.A640T | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV58703694, COSV58709931; called by muse, mutect2, varscan2
- NAA16 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775477193, COSV65065235; called by muse, mutect2
- NAV3 | c.3296C>T p.S1099F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57081171; called by muse, mutect2, varscan2
- NAV3 | c.6166G>A p.G2056R (on ENST00000397909 / NM_001024383.2; = p.G2034R on NM_014903.6) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57081186; called by muse, mutect2, varscan2
- NEFL | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55336242; called by muse, mutect2, varscan2
- NEU4 | c.1421G>A p.G474E (on ENST00000391969 / NM_001167602.3; = p.G486E on NM_080741.4) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57992451; called by muse, mutect2, varscan2
- NISCH | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as rs779642718, COSV61900065; called by muse, mutect2, varscan2
- NOC3L | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV64929939, COSV64930448; called by muse, mutect2, varscan2
- NOS2 | c.2693C>T p.S898F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58223909, COSV58223958; called by muse, mutect2, varscan2
- NPHS1 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62287947; called by muse, mutect2, varscan2
- NRF1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 100/263 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56212391; called by muse, mutect2, varscan2
- NRG3 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV64562880; called by muse, mutect2, varscan2
- NRXN3 | c.1870C>T p.R624* (on ENST00000335750 / NM_001330195.2; = p.R251* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 22/33 reads (67%) | catalogued as COSV59751395; called by muse, mutect2, varscan2
- NT5DC2 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58736519; called by muse, mutect2, varscan2
- NTM | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs780699087, COSV66180298; called by muse, mutect2, varscan2
- NUBP2 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51904721; called by muse, mutect2, varscan2
- NXPE3 | c.1177C>T p.L393F | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV56289591; called by muse, mutect2, varscan2
- NYNRIN | c.3100C>T p.L1034F | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.019); catalogued as COSV66841051; called by muse, mutect2, varscan2
- OLAH | c.308G>A p.G103E (on ENST00000378228 / NM_001039702.3; = p.G156E on NM_018324.3) | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65491577, COSV65494707; called by muse, mutect2, varscan2
- OLFML3 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377456012, COSV57435860; called by muse, mutect2, varscan2
- OR10A6 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV59164741; called by muse, mutect2, varscan2
- OR10C1 | c.76G>A p.G26S (on ENST00000622521; = p.G24S on NM_013941.3) | Missense Mutation (SNP) | VAF 104/126 reads (83%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV101010805, COSV65822915; called by muse, mutect2, varscan2
- OR10G4 | c.742C>T p.L248F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.35); catalogued as rs866147961, COSV104413921, COSV57977656; called by muse, mutect2, varscan2
- OR10K2 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV59221245; called by muse, mutect2, varscan2
- OR13C3 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV66165856; called by muse, mutect2, varscan2
- OR13C8 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs867329527, COSV58611239; called by muse, mutect2, varscan2
- OR14C36 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 23/89 reads (26%) | catalogued as rs866905058, COSV58601374; called by muse, mutect2, varscan2
- OR2Z1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60692478; called by muse, mutect2, varscan2
- OR4A16 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as rs1389734335, COSV59041785; called by muse, mutect2, varscan2
- OR4C12 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58860033, COSV58860399; called by muse, mutect2, varscan2
- OR4C15 | c.229G>A p.E77K (on ENST00000314644; = p.E23K on NM_001001920.2) | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58951205, COSV58952974; called by muse, mutect2, varscan2
- OR51A2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs1465407361, COSV66748379; called by muse, mutect2
- OR51A2 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1361270320, COSV66748381; called by muse, mutect2
- OR51S1 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1324449195, COSV59058517, COSV59060565; called by muse, mutect2, varscan2
- OR52K2 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV57834471, COSV57835116; called by muse, mutect2, varscan2
- OR52M1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs538523839, COSV64171769; called by muse, mutect2, varscan2
- OR5B21 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.034); catalogued as rs963346666, COSV100835166, COSV64481932; called by muse, mutect2, varscan2
- OR5M11 | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1257337927, COSV73141788; called by muse, mutect2, varscan2
- OR9A4 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs782069520, COSV71885475; called by muse, mutect2, varscan2
- OR9I1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV56926094; called by muse, mutect2, varscan2
- OSBPL6 | c.1450A>G p.S484G | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV51918492; called by muse, mutect2
- P2RY13 | c.161T>G p.V54G | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV56379608; called by muse, mutect2, varscan2
- PADI6 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 111/264 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV61884752; called by muse, mutect2, varscan2
- PAMR1 | c.1765A>G p.T589A (on ENST00000619888 / NM_001001991.3; = p.T606A on NM_015430.4) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1364174128, COSV53512580; called by muse, mutect2, varscan2
- PAQR9 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 68/176 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV61418094; called by muse, mutect2, varscan2
- PCDHA13 | c.233A>T p.N78I | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV56503231; called by muse, mutect2, varscan2
- PCDHAC2 | c.2149T>A p.F717I | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV53850326; called by muse, mutect2, varscan2
- PCDHB12 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.06); catalogued as COSV53396796; called by muse, mutect2, varscan2
- PCDHB13 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV53396801; called by muse, mutect2, varscan2
- PCDHB4 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 57/198 reads (29%) | catalogued as COSV52022714; called by muse, mutect2, varscan2
- PCDHGA2 | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV53952182; called by muse, mutect2, varscan2
- PCLO | c.8156G>A p.G2719E | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs773627604, COSV61632500; called by muse, mutect2, varscan2
- PCLO | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs372528729; called by muse, mutect2, varscan2
- PCNX2 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV50802931; called by muse, mutect2, varscan2
- PCP4L1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); catalogued as rs1253772768, COSV73440577; called by muse, mutect2
- PDGFB | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745440692, COSV100483485; called by muse, varscan2
- PDGFB | c.66G>A p.G22= | Splice Region (SNP) | VAF 12/24 reads (50%) | catalogued as COSV100483489; called by muse, varscan2
- PDILT | c.919-1G>A p.X307_splice | Splice Site (SNP) | VAF 53/107 reads (50%) | catalogued as COSV56702004; called by muse, mutect2, varscan2
- PHF6 | c.491A>G p.K164R (on ENST00000332070 / NM_032458.3; = p.K165R on NM_032335.3) | Missense Mutation (SNP) | VAF 62/76 reads (82%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV59702294; called by muse, mutect2, varscan2
- PIK3C2B | c.1199C>A p.T400N | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV65803661; called by muse, mutect2, varscan2
- PIK3R3 | c.1291C>T p.H431Y | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV53107420, COSV53110145; called by muse, mutect2, varscan2
- PIK3R6 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.557); catalogued as COSV61003296; called by muse, mutect2, varscan2
- PIP5K1B | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as COSV55248389; called by muse, mutect2, varscan2
- PITPNM3 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV52595757; called by muse, mutect2, varscan2
- PLA2G7 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772204105, COSV51260674; called by muse, mutect2, varscan2
- PLB1 | c.2905G>A p.D969N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); catalogued as COSV59825685; called by muse, mutect2, varscan2
- PLCE1 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV53351582; called by muse, mutect2, varscan2
- PLIN4 | c.3350G>A p.R1117K (on ENST00000301286; = p.R1132K on NM_001367868.2) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1475063685, COSV56690871; called by muse, mutect2, varscan2
- PLS1 | c.842C>T p.T281I | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV61833914; called by muse, mutect2, varscan2
- PLXNA4 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58127749; called by muse, mutect2
- PMFBP1 | c.1756G>A p.D586N (on ENST00000537465; = p.D581N on NM_031293.3) | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1436653279, COSV52824529, COSV99400898; called by muse, mutect2, varscan2
- PNLIPRP1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs959649900, COSV62611937; called by muse, varscan2
- PPP1R3A | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV52880826; called by muse, mutect2, varscan2
- PPP2R2B | c.556G>A p.E186K (on ENST00000394409; = p.E252K on NM_181674.2) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV60765231; called by muse, mutect2, varscan2
- PREX2 | c.2702C>T p.S901F | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV55771253; called by muse, mutect2, varscan2
- PRKCB | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57780439; called by muse, mutect2, varscan2
- PRKDC | c.11983C>T p.P3995S | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV58052737; called by muse, mutect2, varscan2
- PRKG2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 155/559 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867660938, COSV52320273; called by muse, mutect2, varscan2
- PTPRA | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53781913; called by muse, mutect2, varscan2
- PTPRB | c.4678G>A p.D1560N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs778294640, COSV54241229; called by muse, mutect2, varscan2
- PTPRD | c.2539G>A p.V847M | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.482); catalogued as rs143787300, COSV100644111, COSV61947823; called by muse, mutect2, varscan2
- RAD54L2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56578613; called by muse, mutect2, varscan2
- RAG2 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57556544; called by muse, mutect2, varscan2
- RAPGEF4 | c.1975C>T p.Q659* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV51390105; called by muse, mutect2
- RAPGEF5 | c.628G>A p.E210K (on ENST00000401957 / NM_001367602.2; = p.E513K on NM_012294.5) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV59783425; called by muse, mutect2, varscan2
- RASGRF2 | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.011); catalogued as rs1390458294, COSV54130237; called by muse, mutect2, varscan2
- RBBP6 | c.3160C>T p.R1054* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV60505227; called by muse, mutect2, varscan2
- RERGL | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57462005; called by muse, mutect2
- RETSAT | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1458746653, COSV55526226, COSV55529190; called by muse, mutect2, varscan2
- RETSAT | c.773T>C p.V258A | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV55526235; called by muse, mutect2, varscan2
- REV3L | c.4567G>A p.G1523R | Missense Mutation (SNP) | VAF 93/127 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV62619162; called by muse, mutect2, varscan2
- RGS18 | c.466C>T p.H156Y | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV66508251; called by muse, mutect2, varscan2
- RIMBP2 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV55472988; called by muse, mutect2, varscan2
- RIMKLA | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 141/330 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1239629955, COSV68909782; called by muse, mutect2, varscan2
- RNF13 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV60131285; called by muse, mutect2, varscan2
- RNF152 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV57184134; called by muse, mutect2, varscan2
- RORB | c.1085C>T p.S362F (on ENST00000396204 / NM_001365023.1; = p.S351F on NM_006914.4) | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as COSV65333458; called by muse, mutect2, varscan2
- RRP9 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1014160238, COSV51754491, COSV51755573; called by muse, mutect2, varscan2
- RTBDN | c.607T>G p.S203A (on ENST00000393233 / NM_001270444.1; = p.S235A on NM_031429.2) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV59806385; called by muse, mutect2
- RTL10 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as rs1569058709, COSV60735707; called by muse, mutect2, varscan2
- RTN3 | c.476C>T p.P159L (on ENST00000377819 / NM_001265589.2; = p.P140L on NM_201428.3) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV58028912; called by muse, mutect2, varscan2
- RTTN | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766271702, COSV55345113; called by muse, mutect2, varscan2
- RXFP2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs201792081; called by muse, mutect2, varscan2
- SATB2 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.197); catalogued as COSV53484122; called by muse, mutect2, varscan2
- SCEL | c.991G>A p.E331K (on ENST00000349847 / NM_144777.3; = p.E311K on NM_003843.4) | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs201091090, COSV62993300; called by muse, mutect2, varscan2
- SCN5A | c.2273G>A p.G758E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs199473154, CM100670, COSV100347643, COSV61124784; ClinVar: not provided; called by muse, mutect2, varscan2
- SEMA3D | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52393949; called by muse, mutect2, varscan2
- SERPINA10 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs143859072; called by muse, mutect2, varscan2
- SGSM1 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs768586256, COSV68509802; called by muse, mutect2, varscan2
- SHROOM4 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 70/98 reads (71%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV56789551; called by muse, mutect2, varscan2
- SI | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52279650; called by muse, mutect2, varscan2
- SIMC1 | c.2155T>A p.C719S (on ENST00000443967 / NM_001308196.1; = p.C304S on NM_198567.5) | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57903435; called by muse, mutect2, varscan2
- SIPA1L2 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV53390894; called by muse, mutect2, varscan2
- SLC15A3 | c.1640G>A p.G547D | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1175113144, COSV50006570; called by muse, mutect2, varscan2
- SLC17A3 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100645326, COSV62341679; called by muse, mutect2, varscan2
- SLC26A5 | c.1340A>G p.N447S | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749141441, COSV59701920; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A5 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55833176; called by muse, mutect2, varscan2
- SLC6A1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV55115457; called by muse, mutect2, varscan2
- SLC7A6 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 95/141 reads (67%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV54719029; called by muse, mutect2, varscan2
- SLCO1A2 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV56602610; called by muse, mutect2, varscan2
- SMARCC2 | c.2268T>G p.N756K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV57218601; called by muse, mutect2, varscan2
- SNAP91 | c.2065C>T p.Q689* | Nonsense Mutation (SNP) | VAF 26/40 reads (65%) | catalogued as COSV52122749; called by muse, mutect2, varscan2
- SNAP91 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV52122772; called by muse, mutect2, varscan2
- SNTG2 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV57983679; called by muse, mutect2, varscan2
- SORCS1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.297); catalogued as COSV53867905, COSV99544193; called by muse, mutect2, varscan2
- SPAG17 | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV60459294; called by muse, mutect2, varscan2
- SPARCL1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs1253908338, COSV56803735; called by muse, mutect2, varscan2
- SPATA32 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV59303827; called by muse, mutect2, varscan2
- SPEF2 | c.3790G>A p.V1264I | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61548385; called by muse, mutect2, varscan2
- SPG11 | c.6061C>T p.R2021W | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs777943276, COSV55995077; called by muse, mutect2, varscan2
- SPHKAP | c.3225G>A p.W1075* | Nonsense Mutation (SNP) | VAF 47/93 reads (51%) | catalogued as COSV60879794; called by muse, mutect2, varscan2
- SQLE | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV56280886; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2246C>T p.T749I | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59130867; called by muse, mutect2, varscan2
- STXBP5L | c.390T>G p.S130R | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV56502232, COSV56514489; called by muse, mutect2, varscan2
- STXBP5L | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs866064328, COSV56505589; called by muse, mutect2, varscan2
- SULT1E1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.484); catalogued as rs761102787, COSV56947167; called by muse, mutect2, varscan2
- SULT1E1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56946502; called by muse, mutect2, varscan2
- SYNDIG1 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65235152; called by muse, mutect2, varscan2
- SYT10 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV57340746, COSV99951093; called by muse, mutect2
- SYT2 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV66142052; called by muse, mutect2, varscan2
- TACC3 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775626869, COSV57607126; called by muse, mutect2, varscan2
- TAS2R10 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 33/76 reads (43%) | catalogued as COSV53701067; called by muse, mutect2, varscan2
- TBC1D22A | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 48/70 reads (69%) | catalogued as COSV61439497; called by muse, mutect2, varscan2
- TENM4 | c.5329G>A p.E1777K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs1322617772, COSV53611937, COSV53630350; called by muse, mutect2, varscan2
- TET1 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1465708998, COSV65384908; called by muse, mutect2, varscan2
- TEX10 | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 94/148 reads (64%) | SIFT tolerated (0.57); PolyPhen benign (0.065); catalogued as rs758170314, COSV66515520; called by muse, mutect2, varscan2
- TFIP11 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 76/109 reads (70%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as COSV68020721; called by muse, mutect2, varscan2
- THSD7B | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); catalogued as rs747661487, COSV55688773; called by muse, mutect2, varscan2
- THSD7B | c.3922C>T p.L1308F (on ENST00000272643; = p.L1306F on NM_001316349.2) | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.599); catalogued as COSV99751434; called by muse, mutect2, varscan2
- TLE5 | c.110A>C p.Q37P | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55592131; called by muse, mutect2, varscan2
- TLR4 | c.2459C>T p.S820L (on ENST00000355622 / NM_138554.5; = p.S780L on NM_003266.4) | Missense Mutation (SNP) | VAF 80/126 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62923316; called by muse, mutect2, varscan2
- TMC2 | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.414); catalogued as rs1348132772, COSV62653050; called by muse, mutect2, varscan2
- TMEM175 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53278903; called by muse, mutect2, varscan2
- TMEM273 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/40 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.178); catalogued as rs759835709, COSV65152298; called by muse, mutect2, varscan2
- TMEM52B | c.248C>T p.P83L (on ENST00000381923 / NM_001079815.1; = p.P63L on NM_153022.4) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100046376, COSV53728283; called by muse, mutect2, varscan2
- TMPPE | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV56563866, COSV56567533; called by muse, mutect2, varscan2
- TMPRSS11B | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV60292457; called by muse, mutect2, varscan2
- TMPRSS13 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.562); catalogued as rs756956614, COSV70626394; called by muse, mutect2, varscan2
- TNIK | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.202); catalogued as COSV52682992; called by muse, mutect2, varscan2
- TNR | c.3113C>T p.S1038F | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV54886532; called by muse, mutect2, varscan2
- TOX | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV63846237; called by muse, mutect2, varscan2
- TP53BP2 | c.2641C>T p.P881S (on ENST00000343537 / NM_001031685.3; = p.P752S on NM_005426.2) | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59068704; called by muse, mutect2, varscan2
- TRAF6 | c.609C>T p.I203= | Splice Region (SNP) | VAF 21/75 reads (28%) | catalogued as COSV61922553; called by muse, mutect2, varscan2
- TREML2 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV72439126; called by muse, mutect2, varscan2
- TRIM45 | c.615C>A p.F205L | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV56713703, COSV56714163; called by muse, mutect2, varscan2
- TRPS1 | c.999C>A p.F333L (on ENST00000220888 / NM_001330599.2; = p.F346L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV55241174, COSV99629376; called by muse, mutect2, varscan2
- TRPV5 | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV54686002; called by muse, mutect2, varscan2
- TSC22D2 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100721222; called by muse, mutect2
- TSNAXIP1 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV54649888; called by muse, mutect2, varscan2
- TTC12 | c.1955T>C p.L652S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59097922; called by muse, mutect2, varscan2
- TTC23 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs565376889, COSV50441953; called by muse, mutect2, varscan2
- TTC27 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs760457238, COSV58651982; called by muse, mutect2, varscan2
- TTN | c.53776G>A p.V17926M (on ENST00000591111; = p.V10502M on NM_003319.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | PolyPhen possibly damaging (0.506); catalogued as rs1448926202, COSV60076309; called by muse, mutect2, varscan2
- TTN | c.37567G>A p.E12523K (on ENST00000591111; = p.E5099K on NM_003319.4) | Missense Mutation (SNP) | VAF 81/160 reads (51%) | PolyPhen probably damaging (0.915); catalogued as rs1211763723, COSV60076345; called by muse, mutect2, varscan2
- TUBA4A | c.1288A>T p.K430* | Nonsense Mutation (SNP) | VAF 32/139 reads (23%) | catalogued as COSV50278283; called by muse, mutect2, varscan2
- TUBGCP3 | c.896G>A p.W299* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as COSV56187029; called by muse, mutect2, varscan2
- UBA7 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1402091984, COSV61092284; called by muse, mutect2, varscan2
- UBR5 | c.2047C>T p.P683S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV55287717; called by muse, mutect2, varscan2
- UNC13C | c.4852C>T p.P1618S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52874797, COSV99513706; called by muse, mutect2, varscan2
- UNC5C | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71659672; called by muse, mutect2, varscan2
- USH1C | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs755514689, COSV50018751; called by muse, mutect2, varscan2
- USH1G | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV58881486; called by muse, mutect2, varscan2
- USP42 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as COSV60360438; called by muse, mutect2, varscan2
- VGLL1 | c.69G>A p.W23* | Nonsense Mutation (SNP) | VAF 49/69 reads (71%) | catalogued as COSV65703267; called by muse, mutect2, varscan2
- VKORC1L1 | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.5); catalogued as COSV62489116; called by muse, mutect2, varscan2
- VPS16 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV66795166; called by muse, mutect2, varscan2
- VSIG8 | c.634C>A p.H212N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as COSV63652949; called by muse, mutect2, varscan2
- VWF | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as rs61753984, CM061228, CM137958, COSV104373001, COSV54631019; ClinVar: not provided; called by muse, mutect2, varscan2
- WDR83 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs756840407, COSV54418357; called by muse, mutect2, varscan2
- XCL2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.742); catalogued as COSV63194338; called by muse, mutect2, varscan2
- XCR1 | c.904C>T p.L302F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV58569112; called by muse, mutect2, varscan2
- ZAN | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV61805735, COSV61809213; called by muse, mutect2, varscan2
- ZBTB4 | c.2941C>T p.P981S | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1392266820, COSV60139802, COSV60140333; called by muse, mutect2, varscan2
- ZC3HC1 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759468980, COSV61298360; called by muse, mutect2, varscan2
- ZFHX4 | c.4861G>A p.A1621T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50832879; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as rs1170837844, COSV56272880; called by muse, mutect2, varscan2
- ZNF385D | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as COSV55756468; called by muse, mutect2, varscan2
- ZNF552 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66971685; called by muse, mutect2, varscan2
- ZNF556 | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV100298750; called by muse, mutect2, varscan2
- ZNF600 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV57742779; called by muse, mutect2, varscan2
- ZNF623 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs966855865, COSV71697189; called by muse, mutect2, varscan2
- ZNF827 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV65227334; called by muse, mutect2, varscan2
- ZNF835 | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs759851375, COSV73379455; called by muse, mutect2, varscan2
- ZPLD1 | c.1145G>A p.G382E (on ENST00000466937 / NM_001329788.1; = p.G398E on NM_175056.2) | Missense Mutation (SNP) | VAF 98/282 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs960141195, COSV60353691, COSV60356951; called by muse, mutect2, varscan2
- ZSCAN18 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.298); catalogued as COSV53733178, COSV53735929; called by muse, mutect2, varscan2
- ZSWIM2 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.417); catalogued as COSV54574967; called by muse, mutect2, varscan2
- CGB8 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FMN2 | c.3158C>T p.P1053L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, varscan2
- LMNB1 | c.663dup p.K222Efs*3 | Frame Shift Ins (INS) | VAF 36/110 reads (33%) | called by mutect2, pindel, varscan2
- MBNL1 | c.146_149dup p.I51Sfs*6 | Frame Shift Ins (INS) | VAF 39/102 reads (38%) | called by mutect2, pindel, varscan2
- PRAMEF8 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SLC49A4 | c.375_378del p.F125Lfs*8 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by pindel, varscan2
- TPTE | c.1223T>A p.L408H (on ENST00000618007 / NM_199261.4; = p.L390H on NM_199259.4) | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- AADAT | c.558C>T p.P186= | Silent (SNP) | VAF 53/155 reads (34%) | catalogued as COSV61787242; called by muse, mutect2, varscan2
- ABCA13 | c.13386C>T p.I4462= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs375202986, COSV68944313; called by muse, mutect2, varscan2
- ABCB11 | c.3645G>A p.Q1215= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV55591422; called by muse, varscan2
- ABCC9 | c.4281G>A p.L1427= | Silent (SNP) | VAF 45/74 reads (61%) | catalogued as COSV53972522; called by muse, mutect2, varscan2
- ACSM2A | c.582C>T p.F194= (on ENST00000219054; = p.F115= on NM_001308169.2) | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as COSV54584909; called by muse, mutect2, varscan2
- ACTN2 | c.1611G>A p.E537= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV63975103; called by muse, mutect2, varscan2
- ACTN3 | c.699C>T p.P233= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs1207916766, COSV101557839; called by muse, mutect2, varscan2
- ADAM28 | c.2196C>T p.P732= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV56100780; called by muse, mutect2, varscan2
- ADAMTS7 | c.2175C>T p.I725= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV101183110; called by muse, mutect2, varscan2
- ADCY1 | c.1855C>T p.L619= | Silent (SNP) | VAF 91/261 reads (35%) | catalogued as rs1158321063, COSV52034967; called by muse, mutect2, varscan2
- ADGRV1 | c.1353G>A p.P451= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs749412864, COSV67985622; called by muse, mutect2, varscan2
- ADORA3 | c.417C>T p.F139= | Silent (SNP) | VAF 46/198 reads (23%) | catalogued as COSV53985882; called by muse, mutect2, varscan2
- AGBL1 | c.174G>A p.Q58= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as rs60485756, COSV69799886; called by muse, mutect2, varscan2
- AK5 | c.1560C>T p.A520= (on ENST00000354567 / NM_174858.3; = p.A494= on NM_012093.4) | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV60973179; called by muse, mutect2, varscan2
- ALDH1A2 | c.567C>T p.P189= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as rs1439858879, COSV51081791; called by muse, mutect2, varscan2
- ALPK3 | c.4830C>T p.S1610= | Silent (SNP) | VAF 91/203 reads (45%) | catalogued as COSV51933579; called by muse, mutect2, varscan2
- APBA1 | c.291C>T p.I97= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as rs868089767, COSV55228329; called by muse, mutect2, varscan2
- APLNR | c.1005C>T p.S335= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV57242715; called by muse, mutect2, varscan2
- ARHGAP29 | c.1866G>A p.T622= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs766644572, COSV53108997; called by muse, mutect2, varscan2
- ARHGDIA | c.357C>T p.N119= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs371966890; called by muse, mutect2, varscan2
- ARHGEF18 | c.1617C>T p.I539= (on ENST00000359920 / NM_001130955.2; = p.I435= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV60470047; called by muse, mutect2, varscan2
- ARHGEF2 | c.2826C>T p.D942= (on ENST00000361247 / NM_001162383.2; = p.D914= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 68/128 reads (53%) | catalogued as COSV58111394; called by muse, varscan2
- ARHGEF2 | c.2799C>T p.P933= (on ENST00000361247 / NM_001162383.2; = p.P905= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 58/98 reads (59%) | catalogued as rs754651719, COSV58116268; called by muse, varscan2
- ARHGEF35 | c.1095G>A p.K365= | Silent (SNP) | VAF 39/58 reads (67%) | catalogued as COSV65312680; called by muse, mutect2, varscan2
- ARID4B | c.3612C>T p.L1204= | Silent (SNP) | VAF 35/143 reads (24%) | catalogued as rs537264192, COSV51603551; called by muse, mutect2, varscan2
- ATG16L2 | c.1530C>T p.L510= | Silent (SNP) | VAF 211/607 reads (35%) | catalogued as COSV58361790; called by muse, mutect2, varscan2
- ATG2A | c.1797C>T p.A599= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs370825464; called by muse, mutect2, varscan2
- ATP12A | c.1782G>A p.P594= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs1452581735, COSV54513773; called by muse, mutect2, varscan2
- B4GALT5 | c.144C>A p.A48= | Silent (SNP) | VAF 130/202 reads (64%) | catalogued as COSV65493905; called by muse, mutect2, varscan2
- BAZ2A | c.5676C>T p.S1892= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV51637067; called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- BRPF3 | c.3402C>T p.F1134= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV60207553; called by muse, mutect2, varscan2
- C1orf127 | c.1239G>A p.Q413= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV65437340; called by muse, mutect2, varscan2
- C3orf20 | c.12C>T p.I4= | Silent (SNP) | VAF 87/196 reads (44%) | catalogued as rs201133677, COSV53785621; called by muse, mutect2, varscan2
- C6orf118 | c.312G>A p.R104= | Silent (SNP) | VAF 73/116 reads (63%) | catalogued as COSV57815204; called by muse, mutect2, varscan2
- C8B | c.291G>A p.G97= | Silent (SNP) | VAF 69/208 reads (33%) | catalogued as COSV64777713; called by muse, mutect2
- C9orf152 | c.123C>T p.F41= | Silent (SNP) | VAF 60/93 reads (65%) | catalogued as COSV68762878; called by muse, mutect2, varscan2
- CA3 | c.60C>T p.F20= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV53409971; called by muse, mutect2, varscan2
- CACNA1A | c.5820C>T p.S1940= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV64197322, COSV64198668; called by muse, mutect2, varscan2
- CACNA1E | c.3309G>A p.E1103= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV100702979, COSV62396116; called by muse, mutect2, varscan2
- CACNA1E | c.5115C>T p.S1705= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as COSV62396133; called by muse, mutect2, varscan2
- CACNA2D3 | c.1944C>T p.S648= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV55540515; called by muse, mutect2, varscan2
- CACNA2D4 | c.1830G>A p.R610= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV54945884; called by muse, mutect2
- CALCRL | c.732C>T p.A244= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1313418824, COSV66475044, COSV66476024; called by muse, mutect2, varscan2
- CAMTA1 | c.2346C>T p.S782= | Silent (SNP) | VAF 143/453 reads (32%) | catalogued as rs984979941, COSV57897816; called by muse, mutect2, varscan2
- CASR | c.960C>T p.F320= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs753011255, COSV56133741; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC146 | c.1857C>T p.I619= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs201497585, COSV53548705; called by muse, mutect2, varscan2
- CCDC185 | c.627C>T p.A209= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as COSV64820928; called by muse, mutect2, varscan2
- CCDC30 | c.1827G>A p.R609= (on ENST00000340612; = p.R566= on NM_001080850.3) | Silent (SNP) | VAF 78/237 reads (33%) | catalogued as COSV59606600; called by muse, mutect2, varscan2
- CCDC33 | c.1314C>T p.A438= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV51498849; called by muse, mutect2, varscan2
- CDK18 | c.840C>T p.L280= (on ENST00000506784 / NM_212503.3; = p.L250= on NM_002596.4) | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV100774015; called by muse, mutect2, varscan2
- CDKN1B | c.207C>T p.P69= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs746849706, COSV57430441; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDKN2A | c.171C>T p.A57= | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as rs876658199, COSV58687724, COSV58705214; ClinVar: likely benign; called by muse, varscan2
- CEMIP2 | c.2784C>T p.V928= | Silent (SNP) | VAF 27/38 reads (71%) | catalogued as COSV65484573; called by muse, mutect2, varscan2
- CFAP92 | c.370C>T p.L124= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV54047495; called by muse, mutect2, varscan2
- CHD7 | c.3978C>T p.L1326= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV71110789; called by muse, mutect2, varscan2
- CLEC5A | c.288G>A p.R96= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV69397254; called by muse, mutect2, varscan2
- CNTLN | c.3216C>T p.S1072= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs751610763, COSV52079545; called by muse, mutect2, varscan2
- COL5A1 | c.1515C>T p.G505= | Silent (SNP) | VAF 46/75 reads (61%) | catalogued as COSV65669201; called by muse, mutect2, varscan2
- COL6A6 | c.942G>A p.K314= | Silent (SNP) | VAF 68/180 reads (38%) | catalogued as COSV62025748; called by muse, mutect2, varscan2
- CPNE5 | c.228C>T p.F76= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs574969645, COSV55195626; called by muse, mutect2, varscan2
- CREBBP | c.852A>T p.G284= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV52124498; called by muse, mutect2, varscan2
- CWH43 | c.222G>A p.R74= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs765487564, COSV56939096; called by muse, mutect2
- CYLC1 | c.1422G>A p.K474= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV61412268; called by muse, mutect2
- CYP11B1 | c.126C>T p.P42= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV52827375; called by muse, mutect2, varscan2
- CYP2C19 | c.561C>T p.F187= | Silent (SNP) | VAF 39/76 reads (51%) | catalogued as rs895214411, COSV64906855; called by muse, mutect2, varscan2
- CYP4F2 | c.339C>T p.A113= | Silent (SNP) | VAF 111/245 reads (45%) | catalogued as COSV50001334; called by muse, mutect2, varscan2
- DGCR2 | c.210C>G p.T70= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV54218608, COSV99593854; called by muse, mutect2, varscan2
- DLC1 | c.2712C>T p.P904= (on ENST00000276297 / NM_001348081.2; = p.P467= on NM_006094.5) | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs749152245, COSV52305385; called by muse, mutect2, varscan2
- DNAH1 | c.4602C>T p.I1534= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV70229192; called by muse, mutect2, varscan2
- DNAH3 | c.9087G>A p.K3029= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV54523264; called by muse, mutect2, varscan2
- DNAH5 | c.11268G>A p.R3756= | Silent (SNP) | VAF 76/126 reads (60%) | catalogued as COSV54226088; called by muse, mutect2, varscan2
- DNAH7 | c.6858C>T p.I2286= | Silent (SNP) | VAF 77/161 reads (48%) | catalogued as rs771896188, COSV100415626, COSV56765911; called by muse, mutect2, varscan2
- DOCK3 | c.3351C>T p.I1117= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV56522548; called by muse, mutect2, varscan2
- DPY19L1 | c.753C>T p.F251= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV100204640, COSV60582436; called by muse, mutect2, varscan2
- DVL2 | c.198G>T p.V66= | Silent (SNP) | VAF 53/78 reads (68%) | catalogued as COSV99138527; called by mutect2, varscan2
- EFTUD2 | c.1419C>T p.P473= | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as COSV68183152; called by muse, mutect2, varscan2
- ELANE | c.573G>A p.R191= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as CM098899, COSV55048118; called by muse, mutect2, varscan2
- EML5 | c.306G>A p.K102= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV61345855; called by muse, mutect2, varscan2
- ENPEP | c.2508G>A p.L836= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as rs1216893457, COSV54451391; called by muse, mutect2, varscan2
- ENPP3 | c.618C>T p.F206= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs1006375417, COSV62954312; called by muse, mutect2, varscan2
- EPHA7 | c.2499A>T p.G833= | Silent (SNP) | VAF 33/43 reads (77%) | catalogued as COSV65183078; called by muse, mutect2, varscan2
- EPS8L3 | c.132C>T p.V44= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV62609525; called by muse, mutect2, varscan2
- ERICH3 | c.3858G>A p.R1286= | Silent (SNP) | VAF 61/238 reads (26%) | catalogued as rs200077914, COSV58601509, COSV58607167; called by muse, varscan2
- ESPN | c.429C>T p.H143= | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as COSV64704403; called by muse, mutect2, varscan2
- EXT1 | c.1611C>T p.V537= | Silent (SNP) | VAF 53/240 reads (22%) | catalogued as rs772636953, COSV65479693; called by muse, mutect2, varscan2
- EZHIP | c.1212C>T p.V404= | Silent (SNP) | VAF 31/38 reads (82%) | catalogued as COSV100539728; called by muse, mutect2, varscan2
- FAM184A | c.2511G>A p.R837= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV58854559; called by muse, mutect2, varscan2
- FBN2 | c.1194C>T p.I398= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs766004910, COSV52514657; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FCRL5 | c.2061C>T p.S687= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV62514776; called by muse, mutect2, varscan2
- FER1L6 | c.15G>A p.K5= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs1328654389, COSV67550045, COSV67552891; called by muse, mutect2, varscan2
- FOCAD | c.2652C>T p.H884= | Silent (SNP) | VAF 86/123 reads (70%) | catalogued as COSV58099454; called by muse, mutect2, varscan2
- FOXA3 | c.870G>A p.G290= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs1469598232, COSV56216082; called by muse, mutect2, varscan2
- GABRA4 | c.144C>T p.F48= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs1560487531, COSV51928273, COSV99973549; called by muse, mutect2, varscan2
- GABRG1 | c.603C>T p.S201= | Silent (SNP) | VAF 68/153 reads (44%) | catalogued as rs1446211119, COSV54950739, COSV54956699; called by muse, mutect2, varscan2
- GET3 | c.501G>A p.T167= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs758938561, COSV62002394, COSV62002613; called by muse, mutect2, varscan2
- GGTLC1 | c.441C>T p.F147= | Silent (SNP) | VAF 39/230 reads (17%) | catalogued as rs148590178; called by muse, mutect2
- GIPC1 | c.129C>G p.P43= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100600081; called by muse, mutect2, varscan2
- GJC1 | c.831T>C p.Y277= | Silent (SNP) | VAF 89/120 reads (74%) | catalogued as COSV57911344; called by muse, mutect2, varscan2
- GLI3 | c.1206C>T p.P402= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs774831772, COSV67888781; ClinVar: likely benign; called by muse, mutect2
- GLP1R | c.93C>T p.S31= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV64715035; called by muse, mutect2, varscan2
- GMCL1 | c.1248C>T p.F416= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs771839369, COSV57001736; called by muse, mutect2, varscan2
- GPR141 | c.600G>A p.Q200= | Silent (SNP) | VAF 63/198 reads (32%) | catalogued as COSV57732349; called by muse, mutect2, varscan2
- GPR142 | c.1164G>A p.R388= | Silent (SNP) | VAF 47/185 reads (25%) | catalogued as rs1296767530, COSV59519406; called by muse, mutect2, varscan2
- GPR158 | c.1686G>A p.G562= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV66270701; called by muse, mutect2, varscan2
- GPR20 | c.753C>T p.L251= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs754695464, COSV66684480; called by muse, mutect2, varscan2
- GRB14 | c.315G>A p.R105= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as rs1358125561, COSV55738355; called by muse, mutect2, varscan2
- GRID2 | c.468C>T p.I156= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as rs1210026041, COSV56207824; called by muse, mutect2, varscan2
- HARS2 | c.381C>T p.S127= | Silent (SNP) | VAF 63/113 reads (56%) | catalogued as COSV56906899; called by muse, mutect2, varscan2
- HDLBP | c.1413C>T p.I471= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV60495947; called by muse, mutect2, varscan2
- HEXD | c.94C>T p.L32= | Silent (SNP) | VAF 23/144 reads (16%) | catalogued as COSV60064182; called by muse, mutect2, varscan2
- HPSE | c.1194C>T p.F398= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs1200143898, COSV60986251; called by muse, mutect2, varscan2
- HTT | c.8331C>T p.P2777= | Silent (SNP) | VAF 71/175 reads (41%) | catalogued as rs1450381267, COSV100750800; called by muse, mutect2, varscan2
- IDO2 | c.963C>T p.I321= (on ENST00000389060; = p.I334= on NM_194294.2) | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV58425524; called by muse, mutect2, varscan2
- INTS14 | c.1080C>T p.L360= (on ENST00000313182 / NM_001366360.2; = p.L281= on NM_001136043.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV57527169; called by muse, mutect2, varscan2
- IPO8 | c.2529C>T p.I843= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as COSV56241880, COSV56243497; called by muse, mutect2, varscan2
- ITGA2B | c.1767C>T p.F589= | Silent (SNP) | VAF 55/87 reads (63%) | catalogued as COSV52232652; called by muse, mutect2, varscan2
- ITIH4 | c.2445G>A p.K815= | Silent (SNP) | VAF 103/295 reads (35%) | catalogued as COSV56574260; called by muse, mutect2, varscan2
- JAKMIP3 | c.246G>A p.E82= | Silent (SNP) | VAF 28/48 reads (58%) | catalogued as COSV53820978, COSV53823430; called by muse, mutect2, varscan2
- JPH3 | c.588C>T p.F196= | Silent (SNP) | VAF 44/73 reads (60%) | catalogued as rs747932359, COSV52467894; called by muse, mutect2, varscan2
- KCNU1 | c.291C>T p.A97= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV67756175; called by muse, mutect2, varscan2
- KDM2B | c.3453C>T p.L1151= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100997420; called by muse, mutect2, varscan2
- KIF18A | c.1485G>A p.E495= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs1387949096, COSV54183384; called by muse, mutect2, varscan2
- KIF1A | c.1014C>T p.Y338= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1237938827, COSV57489021; called by muse, mutect2, varscan2
- KIF20B | c.3165T>C p.S1055= (on ENST00000371728 / NM_001284259.2; = p.S1015= on NM_016195.4) | Silent (SNP) | VAF 66/105 reads (63%) | catalogued as COSV53307684; called by muse, mutect2, varscan2
- KL | c.930C>T p.D310= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV66308842; called by muse, mutect2, varscan2
- KLHDC3 | c.198C>T p.I66= | Silent (SNP) | VAF 78/90 reads (87%) | catalogued as COSV55064298; called by muse, mutect2, varscan2
- KLHL3 | c.216C>T p.S72= | Silent (SNP) | VAF 29/137 reads (21%) | catalogued as COSV59054341; called by muse, mutect2, varscan2
- KRTAP13-3 | c.414T>G p.P138= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV61879283, COSV61879730; called by muse, mutect2, varscan2
- LDB3 | c.832C>T p.L278= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV53941854; called by muse, mutect2, varscan2
- LILRA6 | c.978C>T p.S326= | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- LILRA6 | c.723G>A p.L241= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99557746; called by muse, mutect2, varscan2
- LMBRD2 | c.1299C>T p.I433= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs187816551, COSV56950263; called by muse, mutect2, varscan2
- LRCH4 | c.550C>T p.L184= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV53826150; called by muse, mutect2, varscan2
- LRG1 | c.582C>T p.D194= | Silent (SNP) | VAF 67/251 reads (27%) | catalogued as COSV56703825; called by muse, mutect2, varscan2
- LRP4 | c.1653G>A p.Q551= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs1185751959, COSV66135948; called by muse, mutect2, varscan2
- LRRC42 | c.255C>T p.S85= | Silent (SNP) | VAF 99/195 reads (51%) | catalogued as rs373260392; called by muse, mutect2, varscan2
- LUZP2 | c.972G>A p.V324= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV61204648; called by muse, mutect2, varscan2
- MAGEE2 | c.1571G>A p.*524= | Silent (SNP) | VAF 39/49 reads (80%) | catalogued as COSV64897763; called by muse, mutect2, varscan2
- MC3R | c.591C>T p.F197= | Silent (SNP) | VAF 110/165 reads (67%) | catalogued as rs1227729060, COSV54763022; called by muse, mutect2, varscan2
- MPP6 | c.72C>T p.F24= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV56038507; called by muse, mutect2, varscan2
- MSLN | c.858G>A p.R286= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV53499584; called by muse, mutect2, varscan2
- MUC16 | c.31461G>A p.K10487= | Silent (SNP) | VAF 202/396 reads (51%) | catalogued as COSV67467607; called by muse, mutect2, varscan2
- MUC21 | c.1242C>T p.S414= | Silent (SNP) | VAF 100/246 reads (41%) | catalogued as COSV66220886; called by muse, mutect2, varscan2
- MUSK | c.2409C>T p.Y803= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV51886644; called by muse, mutect2, varscan2
- MXRA5 | c.8037G>A p.L2679= | Silent (SNP) | VAF 48/67 reads (72%) | catalogued as rs1305582547, COSV54251133, COSV99477073; called by muse, mutect2, varscan2
- MYCBP2 | c.7635C>T p.F2545= (on ENST00000357337; = p.F2583= on NM_015057.5) | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV62020089; called by muse, mutect2, varscan2
- MYCBPAP | c.1594C>T p.L532= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as COSV60407986; called by muse, mutect2, varscan2
- MYH1 | c.3639C>T p.N1213= | Silent (SNP) | VAF 53/75 reads (71%) | catalogued as COSV56848801; called by muse, mutect2, varscan2
- MYH4 | c.264C>T p.I88= | Silent (SNP) | VAF 54/90 reads (60%) | catalogued as COSV55118571, COSV99700372; called by muse, mutect2, varscan2
- MYO1B | c.336A>C p.A112= | Silent (SNP) | VAF 41/181 reads (23%) | catalogued as COSV58431213; called by muse, mutect2, varscan2
- MYOM3 | c.1425G>A p.R475= | Silent (SNP) | VAF 42/131 reads (32%) | catalogued as COSV58394193; called by muse, mutect2, varscan2
- NCKAP5 | c.4839G>A p.T1613= | Silent (SNP) | VAF 53/116 reads (46%) | catalogued as rs1178447718, COSV58426697; called by muse, mutect2, varscan2
- NDST4 | c.1422G>A p.Q474= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs375881591; called by muse, mutect2, varscan2
- NEB | c.5511G>A p.L1837= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV51418513; called by muse, mutect2, varscan2
- NEIL1 | c.570C>T p.P190= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV51228192, COSV51229254; called by muse, mutect2, varscan2
- NEU4 | c.1422G>A p.G474= (on ENST00000391969 / NM_001167602.3; = p.G486= on NM_080741.4) | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100372035; called by muse, mutect2
- NISCH | c.3402C>T p.V1134= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as rs750890542, COSV61900071; called by muse, mutect2, varscan2
- NLRP13 | c.714G>A p.G238= | Silent (SNP) | VAF 71/179 reads (40%) | catalogued as COSV61621899; called by muse, mutect2, varscan2
- NLRP8 | c.1680C>T p.F560= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs1382822080, COSV52585343; called by muse, mutect2, varscan2
- OGDH | c.2685A>T p.P895= | Silent (SNP) | VAF 36/113 reads (32%) | catalogued as COSV56050191; called by muse, mutect2, varscan2
- OPN1SW | c.36C>T p.F12= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV50821825; called by muse, mutect2, varscan2
- OR10T2 | c.408C>T p.I136= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs771683670, COSV57781470; called by muse, mutect2, varscan2
- OR10X1 | c.525G>A p.E175= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV63767373; called by muse, mutect2, varscan2
- OR1F1 | c.597C>T p.I199= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV58961092; called by muse, mutect2, varscan2
- OR2G6 | c.663C>T p.I221= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs949529116, COSV58573571; called by muse, mutect2, varscan2
- OR2J3 | c.828C>T p.F276= | Silent (SNP) | VAF 52/108 reads (48%) | catalogued as COSV65848685; called by muse, mutect2, varscan2
- OR2W3 | c.36C>T p.F12= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV64456913; called by muse, mutect2, varscan2
- OR4F6 | c.42C>T p.F14= | Silent (SNP) | VAF 78/154 reads (51%) | catalogued as COSV61026858; called by muse, mutect2, varscan2
- OR4N5 | c.255C>T p.F85= | Silent (SNP) | VAF 99/163 reads (61%) | catalogued as COSV61320521; called by muse, mutect2, varscan2
- OR51A2 | c.45C>T p.F15= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV66748385; called by muse, mutect2, varscan2
- OR51Q1 | c.864G>A p.V288= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV56179254; called by muse, mutect2, varscan2
- OR5A1 | c.760C>T p.L254= | Silent (SNP) | VAF 101/248 reads (41%) | catalogued as COSV57376757; called by muse, mutect2, varscan2
- OR5D13 | c.180C>T p.I60= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV100686862, COSV62333807; called by muse, mutect2, varscan2
- OR8H1 | c.96C>T p.L32= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as rs141901122; called by muse, mutect2, varscan2
- OSBPL2 | c.693C>T p.T231= (on ENST00000313733 / NM_144498.4; = p.T219= on NM_014835.4) | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as COSV58216788; called by muse, mutect2, varscan2
- PARVG | c.63G>A p.E21= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV63561856; called by muse, mutect2, varscan2
- PBXIP1 | c.939C>T p.L313= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV63777222; called by muse, mutect2, varscan2
- PC | c.150C>T p.I50= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV63080713; called by muse, mutect2, varscan2
- PCDHA4 | c.486C>T p.I162= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV63541811; called by muse, mutect2, varscan2
- PCDHB6 | c.1575C>T p.F525= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV50698785; called by muse, mutect2, varscan2
- PCDHGB4 | c.837C>T p.F279= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV53918400; called by muse, mutect2, varscan2
- PEX5 | c.1746C>T p.A582= (on ENST00000420616; = p.A574= on NM_000319.5) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1565723752, COSV99870948; called by muse, mutect2
- PEX5 | c.1747C>T p.L583= (on ENST00000420616; = p.L575= on NM_000319.5) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1445547751, COSV99870951; called by muse, mutect2
- PGM1 | c.336C>T p.I112= | Silent (SNP) | VAF 139/260 reads (53%) | catalogued as rs776021665, COSV64300551; called by muse, varscan2
- PHF20 | c.2172G>T p.L724= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV64975933; called by muse, mutect2, varscan2
- PIAS4 | c.528C>T p.I176= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV53679234; called by muse, mutect2, varscan2
- PKD1 | c.6066G>A p.S2022= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs559859602, COSV51916743; called by muse, mutect2, varscan2
- PLCB4 | c.2976C>T p.L992= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs760922623, COSV53794488; called by muse, mutect2
- PLCL1 | c.765G>A p.G255= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs956489022, COSV70833714; called by muse, mutect2, varscan2
- PLXNA2 | c.2670C>T p.I890= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs1323600270, COSV65440915; called by muse, mutect2, varscan2
- PPDPFL | c.9C>T p.S3= | Silent (SNP) | VAF 82/196 reads (42%) | catalogued as rs748569046, COSV57461253; called by muse, mutect2, varscan2
- PPP1R3B | c.765C>T p.S255= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as COSV60099517; called by muse, mutect2, varscan2
- PRLR | c.1632G>A p.K544= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV51495850; called by muse, mutect2, varscan2
- PSMD1 | c.1540C>T p.L514= | Silent (SNP) | VAF 62/138 reads (45%) | catalogued as COSV58079043; called by muse, mutect2, varscan2
- PTCRA | c.414G>A p.E138= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV58975758; called by muse, mutect2, varscan2
- PTPRD | c.5409C>T p.F1803= | Silent (SNP) | VAF 38/57 reads (67%) | catalogued as COSV61947776; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1725C>T p.F575= | Silent (SNP) | VAF 107/159 reads (67%) | catalogued as rs905616656, COSV52863255; called by muse, mutect2, varscan2
- RBM41 | c.117C>T p.S39= | Silent (SNP) | VAF 42/56 reads (75%) | catalogued as COSV52563480; called by muse, mutect2, varscan2
- RFC1 | c.129C>T p.I43= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as rs761691796, COSV62899700; called by muse, mutect2, varscan2
- RHBG | c.984C>T p.I328= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV54801762; called by muse, mutect2, varscan2
- SATB2 | c.978C>T p.L326= | Silent (SNP) | VAF 50/115 reads (43%) | catalogued as rs1559175026, COSV53484133; called by muse, mutect2, varscan2
- SCN11A | c.105G>A p.K35= | Silent (SNP) | VAF 72/205 reads (35%) | catalogued as rs780129768, COSV56570695, COSV56579098; called by muse, varscan2
- SCTR | c.582C>T p.I194= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV50028153; called by muse, mutect2, varscan2
- SEPTIN11 | c.873C>T p.T291= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV53582392; called by muse, mutect2, varscan2
- SERPINB3 | c.340C>T p.L114= | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as COSV52191739, COSV52192906; called by muse, mutect2, varscan2
- SHANK1 | c.78C>T p.S26= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV53251047; called by muse, mutect2, varscan2
- SHROOM1 | c.2541C>T p.F847= (on ENST00000378679 / NM_001172700.2; = p.F842= on NM_133456.2) | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs749059285, COSV60581353; called by muse, mutect2, varscan2
- SI | c.975C>T p.I325= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV52265984, COSV52279634; called by muse, mutect2, varscan2
- SIGLEC12 | c.1662C>T p.A554= (on ENST00000291707 / NM_053003.4; = p.A436= on NM_033329.2) | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV52461707; called by muse, mutect2, varscan2
- SLC25A18 | c.450C>T p.S150= | Silent (SNP) | VAF 62/202 reads (31%) | catalogued as COSV53658157; called by muse, mutect2, varscan2
- SLC29A4 | c.615G>A p.G205= | Silent (SNP) | VAF 38/201 reads (19%) | catalogued as COSV51874354; called by muse, mutect2, varscan2
- SLC39A5 | c.279C>T p.S93= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV57191811; called by muse, mutect2, varscan2
- SLC39A8 | c.807C>T p.I269= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs1423630937, COSV63222719; called by muse, mutect2, varscan2
- SLC5A12 | c.855C>T p.I285= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV54821420; called by muse, mutect2, varscan2
- SLC5A8 | c.909C>T p.S303= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV73310680; called by muse, mutect2
- SLC6A9 | c.402G>A p.G134= (on ENST00000360584 / NM_201649.4; = p.G80= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV62210857, COSV62211723; called by muse, mutect2, varscan2
- SLC9A2 | c.1344C>T p.L448= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as COSV52132248; called by muse, mutect2, varscan2
- SLIT2 | c.4512C>T p.F1504= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs370110126; called by muse, mutect2, varscan2
- SLIT3 | c.387C>T p.F129= | Silent (SNP) | VAF 60/118 reads (51%) | catalogued as COSV60609097; called by muse, mutect2, varscan2
- SPINT2 | c.351G>A p.Q117= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV56647940; called by muse, mutect2, varscan2
- SPNS1 | c.534C>T p.L178= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV57954773; called by muse, mutect2, varscan2
- SPON1 | c.2391G>A p.K797= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV59961514; called by muse, mutect2, varscan2
- STK35 | c.871C>T p.L291= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1452654271, COSV55690646; called by muse, mutect2, varscan2
- SYT1 | c.720C>T p.I240= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs1378146593, COSV54048701; called by muse, mutect2, varscan2
- TACC3 | c.2385C>T p.A795= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs760942064, COSV100508733; called by muse, mutect2, varscan2
- TBC1D10A | c.270C>T p.L90= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as rs747211182, COSV53164336; called by muse, mutect2, varscan2
- TGFB1I1 | c.756C>T p.F252= (on ENST00000394863 / NM_001042454.3; = p.F235= on NM_015927.4) | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs1369175639, COSV62357980; called by muse, mutect2, varscan2
- TGFBR3 | c.1680C>T p.S560= | Silent (SNP) | VAF 139/498 reads (28%) | catalogued as rs758389011, COSV53025720; called by muse, mutect2, varscan2
- THSD7A | c.588C>T p.I196= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs776138415, COSV70265029; called by muse, mutect2, varscan2
- THSD7B | c.3921C>T p.V1307= (on ENST00000272643; = p.V1305= on NM_001316349.2) | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV99751429; called by muse, mutect2, varscan2
- TLR7 | c.2524C>T p.L842= | Silent (SNP) | VAF 85/113 reads (75%) | catalogued as COSV66124354; called by muse, mutect2, varscan2
- TMEM214 | c.1905C>T p.A635= | Silent (SNP) | VAF 45/80 reads (56%) | catalogued as COSV53192689; called by muse, mutect2, varscan2
- TOX2 | c.675C>T p.F225= (on ENST00000358131 / NM_001098798.2; = p.F174= on NM_032883.3) | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV57886547; called by muse, mutect2, varscan2
- TPTE | c.1224C>T p.L408= (on ENST00000618007 / NM_199261.4; = p.L390= on NM_199259.4) | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as rs766505051; called by muse, mutect2, varscan2
- TRHDE | c.3045C>T p.F1015= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV53842088, COSV53857232; called by muse, mutect2, varscan2
- TRPM8 | c.759G>A p.L253= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV61222073; called by muse, mutect2, varscan2
- TRPV5 | c.159C>T p.S53= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV54686015; called by muse, mutect2, varscan2
- TSC22D2 | c.138C>T p.S46= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100721223; called by muse, mutect2, varscan2
- TSPAN8 | c.78C>T p.I26= | Silent (SNP) | VAF 59/205 reads (29%) | catalogued as COSV56078693; called by muse, mutect2, varscan2
- TTC37 | c.1005C>T p.I335= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs774106534, COSV62454858; called by muse, mutect2, varscan2
- TTN | c.100764A>C p.T33588= (on ENST00000591111; = p.T26164= on NM_003319.4) | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as COSV60076269; called by muse, mutect2, varscan2
- TTN | c.31014G>A p.R10338= (on ENST00000591111; = p.R9411= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs1296893267, COSV60076382; called by muse, mutect2, varscan2
- TTN | c.24378C>T p.S8126= (on ENST00000591111; = p.S7199= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as rs1270174085, COSV60076391; called by muse, mutect2, varscan2
- TTN | c.23352C>T p.I7784= (on ENST00000591111; = p.I6857= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs1382027930, COSV60076403; called by muse, mutect2, varscan2
- TTN | c.4131G>A p.G1377= (on ENST00000591111; = p.G1331= on NM_003319.4) | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs777874876, COSV100614257; called by muse, mutect2, varscan2
- TXLNB | c.1500G>A p.V500= | Silent (SNP) | VAF 79/132 reads (60%) | catalogued as rs973437196, COSV64443574; called by muse, mutect2, varscan2
- UBE4B | c.2070C>T p.F690= (on ENST00000343090 / NM_001105562.3; = p.F561= on NM_006048.5) | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as COSV53532862; called by muse, mutect2, varscan2
- UIMC1 | c.2052C>T p.S684= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as COSV65893611; called by muse, mutect2, varscan2
- VAMP7 | c.36C>T p.T12= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV52901912; called by muse, mutect2, varscan2
- VSIG10 | c.318C>T p.I106= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs1178695902, COSV63653450; called by muse, mutect2, varscan2
- VWF | c.99C>T p.A33= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV99779151; called by muse, mutect2, varscan2
- XKRX | c.795G>A p.L265= | Silent (SNP) | VAF 55/74 reads (74%) | catalogued as COSV60708018; called by muse, mutect2, varscan2
- ZNF155 | c.1503C>T p.D501= | Silent (SNP) | VAF 42/108 reads (39%) | catalogued as COSV54206881; called by muse, mutect2, varscan2
- ZNF34 | c.813G>A p.R271= | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV58639552; called by muse, mutect2, varscan2
- ZNF585A | c.789C>T p.I263= (on ENST00000292841 / NM_001288800.2; = p.I208= on NM_152655.3) | Silent (SNP) | VAF 91/172 reads (53%) | catalogued as COSV53063916; called by muse, mutect2, varscan2
- AL590867.2 | n.306T>G | RNA (SNP) | VAF 66/122 reads (54%) | called by muse, mutect2, varscan2
- C3P1 | n.2370C>T | RNA (SNP) | VAF 226/440 reads (51%) | called by muse, mutect2, varscan2
- DEPDC5 | c.1870+2280C>T | Intron (SNP) | VAF 64/114 reads (56%) | catalogued as COSV56697984; called by muse, mutect2, varscan2
- HERC2P3 | n.524G>A | RNA (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- KANSL2 | c.1228-1707G>C | Intron (SNP) | VAF 4/32 reads (13%) | catalogued as COSV101102053; called by muse, mutect2
14 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 14 other) are not listed here.
